Somatic mutation profile of tumor specimen ALCH-ADIU-TTP1-A (aliquot ALCH-ADIU-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADIU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.5 years (22,111 days).
Specimen ALCH-ADIU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1939fa0a-6065-4ac4-a437-7997586214d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADIU-NB1-A (Blood Derived Normal), aliquot ALCH-ADIU-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af2f3f36-4b40-4dab-bf6f-dcea52ee3965

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Translation Start Site 1, Silent 1, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 51/194 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1M1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs1414106796, COSV52229061; called by muse, mutect2
- CCDC51 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 85/472 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56494657; called by muse, mutect2, varscan2
- COG8 | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746569478; called by muse, mutect2, varscan2
- E2F4 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs367663947, COSV62607140; called by muse, mutect2, varscan2
- ELK1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 84/484 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99901795; called by muse, mutect2, varscan2
- FAT3 | c.6172C>T p.R2058C | Missense Mutation (SNP) | VAF 79/434 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs761098787, COSV53150654; called by muse, mutect2, varscan2
- FREM2 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 46/235 reads (20%) | catalogued as COSV99751628; called by muse, mutect2, varscan2
- NMI | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 113/495 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs189993135, COSV54637997; called by muse, mutect2, varscan2
- PCDHGA2 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 22/623 reads (4%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as COSV54040233; called by muse, mutect2
- PLCL1 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV70823947; called by muse, mutect2, varscan2
- VPS45 | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV100964849; called by muse, mutect2, varscan2
- B4GALT2 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CACNA1G | c.6039del p.L2013Ffs*22 | Frame Shift Del (DEL) | VAF 48/265 reads (18%) | called by mutect2, pindel, varscan2
- CNGA2 | c.1616A>T p.N539I | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- DEF6 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/275 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ST3GAL4 | c.464A>G p.Y155C (on ENST00000392669 / NM_001254758.1; = p.Y151C on NM_006278.3) | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.14682C>T p.D4894= (on ENST00000591111; = p.D3967= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/380 reads (14%) | catalogued as rs534365478, COSV100600799; called by muse, mutect2, varscan2
- CEP19 | c.-82A>G | 5'UTR (SNP) | VAF 62/368 reads (17%) | called by muse, mutect2, varscan2
